Somatic mutation profile of tumor specimen TARGET-20-PASZUT-09A (aliquot TARGET-20-PASZUT-09A-01D) from TARGET case TARGET-20-PASZUT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,563 days).
Specimen TARGET-20-PASZUT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d98a6add-bfb0-4916-afa8-d5723eddb081.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASZUT-14A (Bone Marrow Normal), aliquot TARGET-20-PASZUT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a91f4e6-3759-41ff-b189-b19e42359e84

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2505T>G p.D835E | Missense Mutation (SNP) | VAF 20/298 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs121913487, COSV54044297, COSV54045054; ClinVar: pathogenic; called by muse, mutect2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 112/232 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 21/51 reads (41%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLT3 | c.1775T>A p.V592D | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54051432, COSV54058572, COSV54074139; called by muse, mutect2, varscan2
